Somatic mutation profile of tumor specimen TCGA-EM-A3FR-01A (aliquot TCGA-EM-A3FR-01A-11D-A21Z-08) from TCGA case TCGA-EM-A3FR, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 55.7 years (20,349 days).
Specimen TCGA-EM-A3FR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e912351-37a6-4e5d-bc1d-d1db06b50f91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3FR-10A (Blood Derived Normal), aliquot TCGA-EM-A3FR-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fa916ee-9d2a-44a6-b9d8-39e1aaee638f

The open-access MAF lists 14 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 12, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASAP2 | c.527C>G p.T176S | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.97); catalogued as COSV55635897; called by muse, mutect2, varscan2
- FASN | c.4166T>A p.V1389E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60758283; called by muse, mutect2, varscan2
- GAD2 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52163521; called by muse, mutect2
- GARNL3 | c.1300A>G p.K434E | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.055); catalogued as COSV59226407; called by muse, mutect2
- INPP5D | c.508A>T p.S170C (on ENST00000445964 / NM_001017915.3; = p.S169C on NM_005541.5) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.211); catalogued as COSV64038906; called by muse, mutect2, varscan2
- MUC16 | c.12466A>G p.T4156A | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.041); catalogued as COSV67481011; called by muse, mutect2, varscan2
- PNLDC1 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 115/324 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.191); catalogued as COSV51705338; called by muse, mutect2, varscan2
- SLC9A6 | c.1495G>C p.A499P | Missense Mutation (SNP) | VAF 66/245 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65788611; called by muse, mutect2, varscan2
- SNAI2 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50078648, COSV50079793; called by muse, mutect2, varscan2
- SPOP | c.281C>G p.P94R | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.619); catalogued as COSV61655042; called by muse, mutect2, varscan2
- XPR1 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62559001; called by muse, mutect2, varscan2
- ZNF300 | c.62A>G p.E21G | Missense Mutation (SNP) | VAF 45/298 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51042293; called by muse, mutect2, varscan2
- TG | c.1531_1534del p.N511Efs*15 | Frame Shift Del (DEL) | VAF 32/74 reads (43%) | called by mutect2, pindel, varscan2
- FMNL1 | c.588G>A p.V196= | Silent (SNP) | VAF 51/130 reads (39%) | catalogued as COSV58958173; called by muse, mutect2, varscan2
